Somatic mutation profile of tumor specimen TCGA-AG-A01J-01A (aliquot TCGA-AG-A01J-01A-01W-A00E-09) from TCGA case TCGA-AG-A01J, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-AG-A01J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f42cabb-7621-4054-92a2-018e5b27d408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A01J-10A (Blood Derived Normal), aliquot TCGA-AG-A01J-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5f3de11-51a8-4a85-9e98-cb7f2e07bca1

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 8, Frame Shift Del 2, Intron 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA1 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101037531; called by muse, mutect2, varscan2
- ACP3 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); catalogued as COSV60485575; called by muse, mutect2, varscan2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 71/210 reads (34%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- ARMC1 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99395146; called by muse, mutect2, varscan2
- ATN1 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.078); catalogued as rs782754276, COSV63110738; called by muse, mutect2
- ATP6V0A4 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 170/459 reads (37%) | catalogued as rs1384393001, COSV100023580; called by muse, mutect2, varscan2
- BPTF | c.4710T>A p.N1570K | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100075848, COSV100076543; called by muse, mutect2, varscan2
- CCR1 | c.776T>A p.I259K | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99946792; called by muse, mutect2
- COL5A2 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760569641, COSV66415837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRB1 | c.3434C>T p.S1145F | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100958057, COSV66330738; called by muse, mutect2, varscan2
- DISP1 | c.3964G>A p.V1322I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1328173884, COSV99452029; called by muse, mutect2, varscan2
- ENAM | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV101253299; called by muse, mutect2, varscan2
- EPHA5 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 20/326 reads (6%) | catalogued as COSV56630678; called by muse, mutect2
- FAM110B | c.735A>T p.E245D | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64064631; called by muse, mutect2, varscan2
- FAT3 | c.6644G>C p.G2215A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53099999; called by muse, mutect2, varscan2
- GRHL1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); catalogued as COSV100257490, COSV100258108; called by muse, mutect2
- H2AC15 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs188027160; called by muse, mutect2, varscan2
- HOXC10 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV57726112; called by muse, mutect2, varscan2
- ICE1 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV56822766; called by muse, mutect2, varscan2
- ITGB6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 89/411 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs764638718, COSV51799085, COSV99324648; called by muse, mutect2
- KIAA1109 | c.4577C>G p.S1526C | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52669416; called by muse, mutect2, varscan2
- KIAA1755 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99642571; called by muse, mutect2
- KIT | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs139694927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC52 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs137892314; called by muse, mutect2, varscan2
- MACF1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 43/206 reads (21%) | catalogued as COSV100486117; called by muse, mutect2, varscan2
- MAGEC1 | c.3276G>T p.K1092N | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53570964, COSV53573276; called by muse, mutect2, varscan2
- MAP1A | c.5969T>G p.L1990R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.931); catalogued as COSV55807864; called by muse, mutect2, varscan2
- MAP2 | c.3612C>G p.S1204R | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs952017696, COSV99561479; called by muse, mutect2, varscan2
- MED12L | c.5502A>T p.P1834= | Splice Region (SNP) | VAF 63/315 reads (20%) | catalogued as COSV99853187, COSV99854398; called by muse, mutect2, varscan2
- MGLL | c.241G>A p.G81R (on ENST00000398104 / NM_001003794.2; = p.G91R on NM_007283.6) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778074591, COSV54024441, COSV54030457; called by muse, mutect2, varscan2
- MICAL3 | c.1559G>C p.R520P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52895588; called by muse, mutect2, varscan2
- MYO3A | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200879713; called by muse, mutect2, varscan2
- NEO1 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99982694; called by muse, mutect2, varscan2
- NPAT | c.3599C>G p.S1200C | Missense Mutation (SNP) | VAF 171/661 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV53717586, COSV99586343; called by muse, mutect2, varscan2
- OR6C74 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100667828; called by muse, mutect2, varscan2
- PCDH11X | c.2760T>G p.N920K | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV100011440, COSV53458569; called by muse, mutect2
- PCDHB2 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV50580029; called by muse, mutect2, varscan2
- PDE5A | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53350135; called by muse, mutect2, varscan2
- PEX6 | c.1128C>T p.P376= | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99769950; called by muse, mutect2
- PHTF1 | c.2062A>C p.K688Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1448210920, COSV100760178; called by muse, mutect2
- PNLIP | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs1443308378, COSV65041059; called by muse, mutect2
- PPP1R12B | c.2353T>G p.L785V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99295216; called by muse, mutect2, varscan2
- RGL2 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV101004831; called by muse, mutect2, varscan2
- RNF34 | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196981863, COSV63442220; called by muse, mutect2, varscan2
- RTL8B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV101195647; called by muse, mutect2, varscan2
- RUNX1T1 | c.1490C>T p.A497V (on ENST00000265814 / NM_001198628.1; = p.A470V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs763527961, COSV56143789, COSV99752876; called by mutect2, varscan2
- SLC18B1 | c.1298G>T p.R433I | Missense Mutation (SNP) | VAF 260/573 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99259033, COSV99259304; called by muse, mutect2, varscan2
- SLC27A6 | c.1346T>G p.L449R | Missense Mutation (SNP) | VAF 152/608 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99323378; called by muse, mutect2, varscan2
- SLC30A2 | c.579C>A p.Y193* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | catalogued as COSV100958616; called by muse, mutect2, varscan2
- ST18 | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99390835; called by muse, mutect2
- TAF9B | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100540753, COSV59372558; called by muse, mutect2, varscan2
- TARBP1 | c.1739G>C p.R580P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as COSV99242010; called by muse, mutect2, varscan2
- TBC1D8B | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372432035, COSV52175489; called by muse, mutect2, varscan2
- TECTA | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1452561308, COSV50751217; called by muse, varscan2
- TGFBR1 | c.524C>G p.T175S | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as COSV100895435; called by muse, mutect2, varscan2
- TM9SF4 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99455074; called by muse, mutect2
- TNR | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1364498033, COSV99691181; called by muse, mutect2, varscan2
- TNRC6A | c.2771A>G p.D924G | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV100170404; called by muse, mutect2, varscan2
- TTN | c.86784G>C p.K28928N (on ENST00000591111; = p.K21504N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/248 reads (4%) | PolyPhen benign (0.399); catalogued as rs1060500543, COSV59995489; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.83791G>A p.E27931K (on ENST00000591111; = p.E20507K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | PolyPhen probably damaging (0.994); catalogued as COSV60139992; called by muse, mutect2, varscan2
- USH2A | c.3800C>T p.A1267V | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768141777, COSV56384831; called by muse, mutect2, varscan2
- USH2A | c.3551T>A p.L1184* | Nonsense Mutation (SNP) | VAF 18/361 reads (5%) | catalogued as COSV100241209, COSV104408062; called by muse, mutect2
- VBP1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99660974; called by muse, mutect2, varscan2
- ZNF382 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 94/409 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.247); catalogued as rs533817629, COSV99498052; called by muse, mutect2, varscan2
- ZNF630 | c.1507A>T p.I503F | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV52095987; called by muse, mutect2, varscan2
- ZNF638 | c.5393A>C p.K1798T | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as COSV100039694; called by muse, mutect2, varscan2
- ZNF711 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV52152663, COSV52159010, COSV99341510; called by muse, mutect2, varscan2
- ARHGAP25 | c.97_110del p.A33Ifs*44 (on ENST00000409202 / NM_001007231.3; = p.A26Ifs*44 on NM_014882.3) | Frame Shift Del (DEL) | VAF 664/965 reads (69%) | called by mutect2, pindel, varscan2
- DSEL | c.2888T>C p.M963T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- MROH9 | c.869A>G p.K290R | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- NCKAP1L | c.3331G>T p.V1111F | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5T3 | c.371dup p.C124Wfs*10 | Frame Shift Ins (INS) | VAF 124/584 reads (21%) | called by mutect2, pindel, varscan2
- SLC16A5 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- TGS1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- ZNF12 | c.1895_1944del p.P632Hfs*5 (on ENST00000405858 / NM_016265.4; = p.P594Hfs*5 on NM_006956.3) | Frame Shift Del (DEL) | VAF 148/394 reads (38%) | called by mutect2, pindel
- AKTIP | c.333C>T p.F111= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV50875576; called by muse, mutect2, varscan2
- BTN2A2 | c.1476C>T p.P492= | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as COSV100760583, COSV61857140; called by muse, mutect2, varscan2
- CCSER2 | c.852A>G p.E284= | Silent (SNP) | VAF 22/519 reads (4%) | catalogued as COSV99826371; called by muse, mutect2
- COL4A5 | c.1728C>A p.G576= | Silent (SNP) | VAF 61/221 reads (28%) | catalogued as rs1400838317, COSV100089453; called by muse, mutect2, varscan2
- DNAH11 | c.1449A>G p.E483= | Silent (SNP) | VAF 73/204 reads (36%) | catalogued as COSV100180476; called by muse, mutect2, varscan2
- ELOVL6 | c.438C>T p.I146= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100165431; called by muse, mutect2, varscan2
- FAM47B | c.1077C>T p.D359= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as rs770049861, COSV61453958; called by muse, mutect2, varscan2
- FOXS1 | c.732C>T p.I244= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs199689145; called by muse, mutect2
- GPR39 | c.112C>T p.L38= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1350526964, COSV100258403; called by muse, mutect2, varscan2
- ITGA2 | c.3384C>T p.A1128= | Silent (SNP) | VAF 79/344 reads (23%) | catalogued as rs376779752; called by muse, mutect2, varscan2
- NOX4 | c.1113T>G p.L371= | Silent (SNP) | VAF 16/352 reads (5%) | catalogued as COSV54451428; called by muse, mutect2
- OR2F1 | c.879G>A p.R293= | Silent (SNP) | VAF 26/327 reads (8%) | catalogued as COSV67330768; called by muse, mutect2
- OTOA | c.490C>T p.L164= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99625601; called by muse, mutect2, varscan2
- PCDHB12 | c.1530C>T p.N510= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1554286944, COSV53394324, COSV99507721; called by muse, mutect2, varscan2
- POLR1G | c.174G>A p.G58= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100338328; called by muse, mutect2, varscan2
- PRSS37 | c.222C>T p.D74= | Silent (SNP) | VAF 41/220 reads (19%) | catalogued as rs200503952, COSV63339074, COSV63340270; called by muse, mutect2, varscan2
- RP1 | c.1965A>G p.T655= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs777274251, COSV99608591; called by muse, mutect2, varscan2
- SMARCA5 | c.1875C>G p.L625= | Silent (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- TMTC4 | c.2028C>T p.L676= (on ENST00000376234 / NM_001350577.2; = p.L695= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs148530984; called by muse, mutect2, varscan2
- XKR4 | c.1608T>G p.T536= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as COSV59310879; called by muse, mutect2, varscan2
- ZNF250 | c.1101C>T p.Y367= | Silent (SNP) | VAF 75/168 reads (45%) | catalogued as COSV99481042; called by muse, mutect2, varscan2
- ZNF471 | c.1821G>A p.A607= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as rs202243020, COSV57290893; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48014A>C | Intron (SNP) | VAF 25/204 reads (12%) | catalogued as COSV67442844; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23291G>A | Intron (SNP) | VAF 13/64 reads (20%) | catalogued as rs745945267, COSV59384944; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796147 C>T | 5'Flank (SNP) | VAF 6/15 reads (40%) | catalogued as rs1471004358; called by muse, varscan2
